Gene-level copy-number profile of tumor specimen TCGA-Q9-A6FW-01A from TCGA case TCGA-Q9-A6FW, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; AJCC pathologic stage: Stage IIIB; Tumor grade: G2; Age at diagnosis: 61.8 years (22,586 days).
Specimen TCGA-Q9-A6FW-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ESCA.104622c2-b439-45cf-a11e-c449a1edf29c.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-Q9-A6FW-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/f902fccb-01d0-4025-9096-3cc843291a41

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 171; copy number 1: 8,073; copy number 2: 37,258; copy number 3: 9,276; copy number 4: 4,010; copy number 5: 626; copy number 6: 174; copy number 7: 83; copy number 8: 120; copy number 18: 22.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-Q9-A6FW-01A-31D-A31T-01): tumor purity 0.56, ploidy 2.08, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 171 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,802,636–24,905,735, 34 genes: MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1, LINC01239, AL391117.1, CLIC4P1, AC017067.1, AL357614.1, AL445623.2, SUMO2P2, AL445623.1, NOP56P2, ELAVL2, AL161628.1, AL365204.1, AL365204.2, AL365204.3, AL513317.1, IZUMO3, AL353811.1, RMRPP5.
- chr9:38,406,528–43,045,120, 137 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,025 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:69,013,179–72,826,041, 78 genes, copy number 6–8 (within-gene range 4–8) (broad region; genes not listed).
- chr2:75,627,950–77,593,319, 25 genes, copy number 6: U3, MRPL19, SUPT4H1P1, GCFC2, AC005034.3, AC005034.5, AC005034.2, AC005034.6, AC005034.4, AC110614.1, SUCLA2P2, AC073091.1, AC073091.2, PNPP1, USP21P2, RN7SKP203, RN7SKP164, AC068616.2, AC068616.3, AC068616.1, LRRTM4, RNA5SP98, AC079117.1, LRRTM4-AS1, AC013716.1.
- chr3:8,733,802–15,859,771, 176 genes, copy number 5–7 (within-gene range 3–7) (broad region; genes not listed).
- chr7:70,972–11,832,198, 231 genes, copy number 5 (broad region; genes not listed).
- chr7:93,844,789–95,544,542, 37 genes, copy number 6: NDUFAF4P2, TFPI2, TFPI2-DT, AC002076.1, GNG11, AC006378.1, BET1, BET1-AS1, AC003092.1, AC003092.2, AC002074.1, AC002074.2, COL1A2, RNU6-1328P, CASD1, SGCE, PEG10, RPS3AP25, RNU6-956P, ATP5PBP2, GRPEL2P3, RN7SKP129, ARF1P1, PPP1R9A, HINT1P2, AC002429.1, PPP1R9A-AS1, RNU4-16P, PON1, AC004022.2, AC004022.1, PON3, PON2, AC005021.1, AC004012.1, ASB4, AC002451.2.
- chr7:99,027,440–100,221,488, 66 genes, copy number 6 (within-gene range 3–6) (broad region; genes not listed).
- chr9:14,475–11,436,244, 157 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr9:19,026,892–20,995,955, 35 genes, copy number 5 (within-gene range 2–5): AL356000.1, RRAGA, HAUS6, SCARNA8, RNU6-264P, Y_RNA, PLIN2, AL161909.1, DENND4C, AL161909.2, AL391834.1, AL391834.2, RPS6, NDUFA5P3, AL391834.3, ACER2, AL158206.1, MAP1LC3BP1, SLC24A2, C11orf98P1, AL158077.2, AL158077.1, AL591222.1, AL591222.2, AL591222.3, AL512635.1, MLLT3, MIR4473, RNU4-26P, MIR4474, AL163193.1, FOCAD, FOCAD-AS1, MIR491, SNORA30B.
- chr10:31,187,715–38,783,108, 140 genes, copy number 5–18 (within-gene range 1–18) (broad region; genes not listed).
- chr18:14,377,546–21,704,780, 51 genes, copy number 5: TERF1P2, FEM1AP2, AP006261.1, LONRF2P1, CXADRP3, GRAMD4P7, POTEC, RNU6-1021P, OR4K7P, OR4K8P, SNX19P3, VN1R74P, GTF2IP8, ANKRD30B, RNU6-1210P, AP006565.1, MIR3156-2, LINC01906, FGF7P1, AP005121.1, LINC01443, LINC01444, AP005121.2, AP005242.4, AP005242.2, AP005242.3, AP005242.1, AP005242.5, AP005901.2, AP005901.6, AP005901.5, AP005901.3, BNIP3P3, AP005901.4, AP005901.1, RNU6-721P, ROCK1, AC022795.1, RNU6-120P, EXOGP1, AC022809.1, GREB1L, AC015878.2, AC015878.1, AC011774.1, ESCO1, SNRPD1, ABHD3, AC106037.2, AC106037.3, MIR320C1.
- chr18:21,711,950–21,724,229, 2 genes, copy number 5: AC106037.1, Y_RNA.
- chr18:21,981,121–22,348,252, 10 genes, copy number 8 (within-gene range 1–8): LINC01900, AC091043.1, RNU6ATAC20P, GATA6-AS1, GATA6, AC091588.1, RNU6-702P, AC091588.3, AC091588.2, AC027449.1.
- chr18:23,672,253–24,397,880, 17 genes, copy number 7 (within-gene range 2–7): RPS10P27, LAMA3, RPL23AP77, AC010754.1, TTC39C, TTC39C-AS1, AC090772.2, AC090772.1, RNU5A-6P, AC090772.4, CABYR, AC090772.3, OSBPL1A, RNA5SP452, Metazoa_SRP, RNU6-435P, MIR320C2.

Autosomal genes at a single copy (total copy number 1): 5,687. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
